Gene-level copy-number profile of tumor specimen TCGA-36-2549-01A from TCGA case TCGA-36-2549, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 55.0 years (20,076 days).
Specimen TCGA-36-2549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ad6d5939-7ddd-41e6-b5a5-f45e8e2f94ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2549-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ef911ec-1c30-4598-ab31-632440bfa66c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,279; copy number 2: 38,882; copy number 3: 7,055; copy number 4: 1,441; copy number 5: 586; copy number 6: 403; copy number 7: 172.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-2549-01): tumor purity 0.85, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,161 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:143,316,111–145,040,941, 67 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:104,330,324–145,066,685, 599 genes, copy number 5–7 (broad region; genes not listed).
- chr12:66,767–13,982,002, 495 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
